Gene-level copy-number profile of tumor specimen TCGA-OR-A5K3-01A from TCGA case TCGA-OR-A5K3, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 53.0 years (19,375 days).
Specimen TCGA-OR-A5K3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.c6d8fc41-c1b5-457f-a769-7ad898fdb889.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30657384-2695-4d7d-8bb7-0445b6c48b89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3; copy number 2: 43,046; copy number 3: 300; copy number 4: 15,742; copy number 6: 728.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K3-01A-11D-A29H-01): tumor purity 0.91, ploidy 1.28, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,026,698–117,027,039, 1 gene: PTMAP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 728 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,062,081, 728 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
